Somatic mutation profile of tumor specimen TCGA-IB-7897-01A (aliquot TCGA-IB-7897-01A-21D-2201-08) from TCGA case TCGA-IB-7897, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.0 years (19,718 days).
Specimen TCGA-IB-7897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1eba918-4cbd-4528-bb81-b762d433ba58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7897-10A (Blood Derived Normal), aliquot TCGA-IB-7897-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6900dee1-19be-423a-9d4c-61eb674e06e2

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP2 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 16/526 reads (3%) | catalogued as rs1178491246, COSV63493477; ClinVar: pathogenic; called by muse, mutect2
- MAGEA3 | c.558C>T p.Y186= | Silent (SNP) | VAF 32/1278 reads (3%) | catalogued as rs782480387, COSV100938982; called by muse, mutect2
- PHACTR4 | c.1732C>A p.R578= (on ENST00000373839 / NM_001350159.2; = p.R588= on NM_023923.4) | Silent (SNP) | VAF 38/1586 reads (2%) | catalogued as rs1476544280, COSV65783122; called by muse, mutect2
